Gene-level copy-number profile of tumor specimen HTMCP-03-06-02242-01A from CGCI case HTMCP-03-06-02242, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02242-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7357a5af-22c2-47db-9e8f-cf9573253e58.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02242-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/78f46dc1-b08d-4c92-85a1-0f1e2134c321

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 10,188; copy number 2: 43,152; copy number 3: 3,958; copy number 4: 1,011; copy number 6: 35; copy number 7: 11.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,690,719, 3 genes (within-gene range 0–1): AC104164.2, MIR548BB, PPIAP70.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:39,631,046–39,810,097, 7 genes: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:65,668,805–66,179,474, 19 genes: CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr9:69,472,466–69,494,513, 1 gene (within-gene range 0–2): AL353693.1.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 16 genes, copy number 6: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:73,403,788–73,842,516, 19 genes, copy number 6: Y_RNA, FZD9, BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1, VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27.
- chr8:127,072,694–127,482,139, 7 genes, copy number 7: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr13:63,738,111–63,811,608, 4 genes, copy number 7: AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10.

Autosomal genes at a single copy (total copy number 1): 9,678. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
